Somatic mutation profile of tumor specimen TARGET-10-PAPHWE-09A (aliquot TARGET-10-PAPHWE-09A-01D) from TARGET case TARGET-10-PAPHWE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,570 days).
Specimen TARGET-10-PAPHWE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ddff7c6-4694-4835-ae5b-fc0cd47ef383.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHWE-10A (Blood Derived Normal), aliquot TARGET-10-PAPHWE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3a43aed-9cb7-4cbb-a4d9-5164ad009d77

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 5'UTR 3, Silent 2, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IKZF1 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58780577; called by muse, mutect2, varscan2
- TSC1 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53763931; called by muse, mutect2
- DCHS2 | c.1229G>C p.R410P | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FREM2 | c.7689C>A p.N2563K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SERTM1 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- YLPM1 | c.2852C>A p.P951H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- HTR2C | c.855C>T p.N285= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as rs782359396, COSV52211534; called by muse, mutect2, varscan2
- KRTAP7-1 | c.183C>T p.I61= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as rs1313744544, COSV71879709; called by muse, mutect2, varscan2
- CDH11 | c.-259C>T | 5'UTR (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- DXO | c.948+53A>G | Intron (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- IGHV1-45 | chr14:106506995 ins TT | 3'Flank (INS) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- RFTN2 | c.-76C>A | 5'UTR (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- TXNDC16 | c.-61G>T | 5'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
